CPTAC case C3L-00599 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd0b8083-0403-4334-9f3e-04c8cd9ab108

Demographics
Sex at birth: male; Race: white; Year of birth: 1954; Vital status: Dead; Days to death: 1,352 days (3.7 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Age at diagnosis: 62.4 years (22,781 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,352 days (3.7 years); Progression or recurrence: yes; Days to recurrence: 1,081 days (3.0 years); Days to last follow up: 1,352 days (3.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 9 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 17; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 477 days (1.3 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 670 days (1.8 years); Disease response: Complete Response.
- Days to follow up: 1,236 days (3.4 years); Disease response: Stable Disease; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,305 days (3.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,034 days (2.8 years); Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 1,352 days (3.7 years); Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 77.6 kg; Height: 176 cm; BMI: 25.05; Comorbidities: Hyperlipidemia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00599-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 67 mg; Time between excision and freezing: 31 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00599-23: Section location: Mass centered in the uncinate process; Percent tumor nuclei: 25; Percent necrosis: 0.
- Sample C3L-00599-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 36 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00599-22: Section location: Mass centered in the uncinate process; Percent tumor nuclei: 25; Percent necrosis: 0.
- Sample C3L-00599-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 50.5 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00599-21: Section location: Mass centered in the uncinate process; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3L-00599-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 36 days; Method of sample procurement: Blood Draw.
- Sample C3L-00599-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
